Somatic mutation profile of tumor specimen TCGA-SC-A6LR-01A (aliquot TCGA-SC-A6LR-01A-11D-A34C-32) from TCGA case TCGA-SC-A6LR, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.3 years (26,773 days).
Specimen TCGA-SC-A6LR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 713a4ea3-efb0-4072-8e0c-7f68829b4846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SC-A6LR-10A (Blood Derived Normal), aliquot TCGA-SC-A6LR-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8d0e0a-df83-4f24-bf7a-4fcad6a858e2

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Del 2, In Frame Del 1, Intron 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A4 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as rs1304591878; called by muse, mutect2, varscan2
- COA7 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769081843; called by muse, mutect2, varscan2
- DCLRE1B | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as rs761535143; called by muse, mutect2, varscan2
- DISC1 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV64096164; called by muse, mutect2, varscan2
- EP300 | c.3553A>G p.I1185V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1489896703, COSV54325145; called by muse, mutect2, varscan2
- FRY | c.4627C>T p.Q1543* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV66572342; called by muse, mutect2, varscan2
- H4C4 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1283194147; called by muse, mutect2, varscan2
- IL21R | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.627); catalogued as rs200379224, COSV61969470; called by muse, mutect2, varscan2
- KCNH2 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs199472908, CM097436, COSV51133907; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- MMP20 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1329359405; called by muse, mutect2, varscan2
- NDUFA10 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs747373667; called by muse, mutect2, varscan2
- PAPLN | c.3091G>A p.A1031T (on ENST00000554301; = p.A1004T on NM_173462.4) | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1483428275; called by muse, mutect2, varscan2
- PIK3CA | c.3202A>T p.N1068Y | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55875344; called by muse, mutect2, varscan2
- PLCZ1 | c.1198A>G p.R400G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs964372593; called by muse, mutect2, varscan2
- RAB19 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs189143966, COSV52044445; called by muse, mutect2, varscan2
- SCN1A | c.2686G>A p.V896I (on ENST00000303395 / NM_001202435.3; = p.V885I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.572); catalogued as rs745378416, CM096133, CM1211401, CM127610, COSV57687946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD6 | c.5968G>A p.A1990T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV100287812; called by muse, mutect2, varscan2
- TOP2A | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1242933083; called by muse, mutect2
- TRPM5 | c.906G>A p.L302= | Splice Region (SNP) | VAF 23/94 reads (24%) | catalogued as rs1442433843, COSV99030418; called by muse, mutect2, varscan2
- ACAP1 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ANKRD35 | c.633C>G p.D211E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP4E1 | c.1341del p.F447Lfs*5 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- CCDC88C | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP72 | c.1645A>C p.T549P | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- CHD8 | c.3920del p.L1307* (on ENST00000646647 / NM_001170629.2; = p.L1028* on NM_020920.4) | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.2771G>A p.S924N (on ENST00000377298 / NM_001009566.3; = p.S914N on NM_014944.4) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIP | c.227G>C p.W76S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HDLBP | c.2941T>G p.F981V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- MTHFD2 | c.972_974del p.I326del | In Frame Del (DEL) | VAF 24/121 reads (20%) | called by mutect2, pindel, varscan2
- NUBP2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A2 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SLITRK6 | c.2124G>C p.E708D | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM38 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 98/178 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WWP2 | c.1006T>G p.W336G | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF521 | c.649T>A p.L217I | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP20 | c.828C>T p.L276= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52806366; called by muse, mutect2, varscan2
- BIRC6 | c.5151C>T p.S1717= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as rs147771042; called by muse, mutect2, varscan2
- CERT1 | c.450G>A p.P150= (on ENST00000405807 / NM_001130105.1; = p.P22= on NM_005713.3) | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- CUX1 | c.2976G>A p.T992= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs782060298, COSV52906468; called by muse, mutect2, varscan2
- FAM83G | c.1302C>T p.P434= | Silent (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- FAT4 | c.432C>T p.F144= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs770537616; called by muse, mutect2, varscan2
- SLC20A2 | c.699C>T p.F233= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs149457553; called by muse, mutect2, varscan2
- SMURF1 | c.1062G>A p.Q354= | Silent (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- TRAK1 | c.2715C>T p.I905= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs768056070; called by muse, mutect2, varscan2
- WWP2 | c.1215C>T p.G405= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- CASP10 | c.1415+8079G>T | Intron (SNP) | VAF 31/97 reads (32%) | catalogued as COSV53779939; called by muse, mutect2, varscan2
- SNORD116-17 | n.78G>A | RNA (SNP) | VAF 23/117 reads (20%) | catalogued as rs748586644; called by muse, mutect2, varscan2
